Somatic mutation profile of tumor specimen 0DN1D5 from CCDI case PBCBBT, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Brain stem; Age at diagnosis: 2.9 years (1,048 days).
Specimen 0DN1D5: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b1a464b8-0171-4e69-a445-b159b7301582.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DN1B7 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f034ac4e-5eed-4f2b-8ccb-9aeba1ddf1a1

The open-access MAF lists 6 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 2, Nonsense Mutation 2, 5'UTR 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SLC38A4 | c.1336C>T p.R446* | Nonsense Mutation (SNP) | VAF 46/1294 reads (4%) | catalogued as COSV56968815; called by muse, mutect2
- QRICH1 | c.919G>T p.E307* | Nonsense Mutation (SNP) | VAF 118/424 reads (28%) | called by muse, mutect2, varscan2
- THADA | c.636G>T p.Q212H | Missense Mutation (SNP) | VAF 45/1393 reads (3%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.956); called by muse, mutect2
- CHRNA7 | c.1248C>T p.H416= | Silent (SNP) | VAF 76/480 reads (16%) | catalogued as rs780316084, COSV100181528; called by muse, mutect2, varscan2
- INSRR | c.2055C>T p.S685= | Silent (SNP) | VAF 38/339 reads (11%) | catalogued as COSV63873048; called by muse, mutect2, varscan2
- PPP2R5A | c.-100C>T | 5'UTR (SNP) | VAF 4/30 reads (13%) | called by muse, mutect2
